Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NP, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NP-01A (Primary Tumor).

ICD-O-3

Carcinoma, hepatocellular NOS

8170/3

Site: Liver C22.0

9/12/24/12

TISSUE DESCRIPTION:

A1 B1 C1 C2 C3 C4 C5 C6 C7 C8 C9 C10 C11 C12 C13 C14 C15
C16 C17 C18 C19 C20 C21 C22 C23

Gallbladder (9.0 x 4.0 x 2.4 cm), left portal lymph node (2.0 x 1.3 x 0.8 cm) and left lobe liver (1065 grams, 19.3 x 16.5 x 11.2 cm).

DIAGNOSIS:

Liver, left lobe, resection: Grade 3 (of 4) hepatocellular carcinoma forming a 15.4 x 11.3 x 10.7 cm mass, arising in histologically unremarkable liver. The margins are negative for tumor (closest margin is free by 0.4cm). No necrosis or angiovascular invasion is identified.

Gallbladder, cholecystectomy: Chronic cholecystitis. A single cystic duct lymph node is negative for tumor.

Lymph node, left portal, excision: A single left portal lymph node is negative for tumor.

PHOTOGRAPHED IN LAB.

PRELIMINARY FROZEN SECTION CONSULTATION:

Liver, left lobe, resection: Hepatocellular carcinoma. HOLD OVER for immunostains.

Dual/Overlapping Primary Sites		☒

9/26/12

Source: NCI Genomic Data Commons file f860eff4-5e3e-418d-86e2-72dbfa42081c (TCGA-DD-A4NP.6C7AE628-1BC9-453D-A1C2-5F2F63A295FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).